CCDI case PBCRUZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/c36f52a0-bf67-4fd6-9486-bd3d0d969969

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 1.0 years (372 days).

Biospecimens (2 samples)
- Sample 0DY8KL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY8KM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
